Somatic mutation profile of tumor specimen TCGA-DD-AADD-01A (aliquot TCGA-DD-AADD-01A-11D-A40R-10) from TCGA case TCGA-DD-AADD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 51.3 years (18,752 days).
Specimen TCGA-DD-AADD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ba33112-d6ab-43cb-8f36-4b4df4f44427.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADD-10A (Blood Derived Normal), aliquot TCGA-DD-AADD-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b04b09b-60d2-40aa-8ff2-43867528e8d9

The open-access MAF lists 88 somatic variants for this specimen: 70 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 57, Silent 18, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 2, In Frame Del 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 51/137 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 46/52 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.2744A>G p.E915G | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV101166095; called by muse, mutect2, varscan2
- AL645922.1 | c.3388A>G p.I1130V | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100963775; called by muse, mutect2, varscan2
- APBA2 | c.2105A>G p.E702G | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1417853302, COSV101381974; called by muse, mutect2, varscan2
- AQP2 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99550752; called by muse, mutect2, varscan2
- ATP2B2 | c.2716A>T p.M906L (on ENST00000352432; = p.M872L on NM_001683.5) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100659763; called by muse, mutect2, varscan2
- BICRAL | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100017887; called by muse, mutect2, varscan2
- BRWD1 | c.5628A>G p.I1876M | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.087); catalogued as rs892013386, COSV100312989; called by muse, mutect2, varscan2
- CALML6 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as rs150584821; called by muse, mutect2, varscan2
- CATSPERE | c.1508A>G p.D503G | Missense Mutation (SNP) | VAF 162/355 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100834958; called by muse, mutect2, varscan2
- CFAP36 | c.269C>G p.T90S | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100170785; called by muse, mutect2, varscan2
- CLK2 | c.1427A>T p.H476L (on ENST00000368361 / NM_001294339.2; = p.H475L on NM_003993.4) | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100226608; called by muse, mutect2, varscan2
- CNOT1 | c.5791A>T p.K1931* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as COSV99799443; called by muse, mutect2, varscan2
- DBP | c.913C>A p.R305S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99709202; called by muse, mutect2, varscan2
- DIP2B | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV99998039; called by muse, mutect2, varscan2
- DTX4 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs770051308, COSV57096313; called by muse, mutect2, varscan2
- DUOX1 | c.2252T>A p.M751K | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100367694; called by muse, mutect2, varscan2
- EDN2 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101006313; called by muse, mutect2, varscan2
- EIF3E | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 173/340 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99622860; called by muse, mutect2, varscan2
- EMCN | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.22); catalogued as rs759272822, COSV99597926; called by muse, mutect2, varscan2
- FANCM | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV99950606; called by muse, mutect2, varscan2
- FAT4 | c.9362C>T p.A3121V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1325978882, CM1514847, COSV58693026; called by muse, mutect2, varscan2
- FUBP1 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1033225821, COSV99628033; called by muse, mutect2, varscan2
- GRIP1 | c.2288C>T p.P763L (on ENST00000359742 / NM_001379345.1; = p.P711L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs1220149761, COSV99668404; called by muse, mutect2, varscan2
- HMGXB4 | c.1718C>G p.T573S | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99329952; called by muse, mutect2, varscan2
- HOXA7 | c.502T>G p.C168G | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99636277; called by muse, mutect2, varscan2
- KIF21A | c.1903T>G p.S635A (on ENST00000361418 / NM_001378440.1; = p.S622A on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV100735339; called by muse, mutect2, varscan2
- LAMP5 | c.425A>C p.Q142P | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs761022614, COSV99855475; called by muse, mutect2, varscan2
- LAS1L | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100408489; called by muse, mutect2, varscan2
- LPCAT4 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100148863; called by muse, mutect2, varscan2
- MAP3K6 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1192790793, COSV58869684; called by muse, mutect2
- MMP2 | c.1005C>T p.T335= | Splice Region (SNP) | VAF 12/23 reads (52%) | catalogued as rs745915591; called by muse, mutect2
- MOCOS | c.217A>T p.M73L | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99732904; called by muse, mutect2, varscan2
- MTM1 | c.807A>T p.K269N | Missense Mutation (SNP) | VAF 105/111 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100080238; called by muse, mutect2, varscan2
- MYLK | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 357/780 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV60606922, COSV60606970; called by muse, mutect2, varscan2
- NFRKB | c.643C>T p.L215F (on ENST00000446488 / NM_001143835.2; = p.L240F on NM_006165.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100451809; called by muse, mutect2, varscan2
- NIT2 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769700861, COSV101237078; called by muse, mutect2, varscan2
- NOTCH2 | c.3424A>G p.T1142A | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV99863090; called by muse, mutect2, varscan2
- NXNL1 | c.74A>C p.E25A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100111938; called by muse, mutect2, varscan2
- OR2K2 | c.894A>G p.I298M (on ENST00000374428; = p.I269M on NM_205859.2) | Missense Mutation (SNP) | VAF 139/158 reads (88%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.844); catalogued as rs747616616, COSV100235143; called by muse, mutect2, varscan2
- OR5I1 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100041212; called by muse, mutect2, varscan2
- PPP4R3A | c.972T>A p.D324E | Missense Mutation (SNP) | VAF 82/102 reads (80%) | SIFT tolerated (0.26); PolyPhen benign (0.093); catalogued as COSV100465685; called by muse, mutect2, varscan2
- PUM3 | c.1412+1G>A p.X471_splice | Splice Site (SNP) | VAF 48/57 reads (84%) | catalogued as COSV101146274; called by muse, mutect2, varscan2
- PUS7L | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 140/219 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV100786478; called by muse, mutect2, varscan2
- RALA | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99143354; called by muse, mutect2, varscan2
- RICTOR | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 87/97 reads (90%) | SIFT tolerated (0.53); PolyPhen benign (0.135); catalogued as COSV99704495; called by muse, mutect2, varscan2
- RMDN1 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 164/290 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99547247; called by muse, mutect2, varscan2
- RRP8 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1466326165, COSV99601824; called by muse, mutect2, varscan2
- SCAMP2 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173931; called by muse, mutect2, varscan2
- SCN2A | c.5641del p.E1881Sfs*20 | Frame Shift Del (DEL) | VAF 88/189 reads (47%) | catalogued as COSV99329666; called by mutect2, pindel, varscan2
- SLC16A4 | c.950T>G p.I317S | Missense Mutation (SNP) | VAF 100/178 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100872914; called by muse, mutect2, varscan2
- SMARCA1 | c.2002A>G p.M668V | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100946396; called by muse, mutect2, varscan2
- SMG7 | c.2612G>A p.W871* | Nonsense Mutation (SNP) | VAF 122/252 reads (48%) | catalogued as COSV100750117; called by muse, mutect2, varscan2
- SORL1 | c.3876C>A p.H1292Q | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99493089; called by muse, mutect2, varscan2
- SYNJ2 | c.3484C>T p.P1162S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100840057; called by muse, mutect2, varscan2
- TDRD1 | c.1335T>A p.Y445* | Nonsense Mutation (SNP) | VAF 69/95 reads (73%) | catalogued as COSV99314203; called by muse, mutect2, varscan2
- THSD7B | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV99745794; called by muse, mutect2, varscan2
- TMEM87A | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs145141787; called by muse, mutect2, varscan2
- TRHDE | c.2383C>A p.P795T | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as COSV99669478; called by muse, mutect2, varscan2
- USP5 | c.100T>G p.F34V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99976802; called by muse, mutect2, varscan2
- UTP6 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55572522, COSV99911827; called by muse, mutect2, varscan2
- WDR77 | c.564+2T>G p.X188_splice | Splice Site (SNP) | VAF 145/277 reads (52%) | catalogued as COSV99330737; called by muse, mutect2, varscan2
- XIRP2 | c.7156C>A p.Q2386K (on ENST00000628543; = p.Q2561K on NM_152381.6) | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99739435; called by muse, mutect2, varscan2
- Z83844.2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 116/269 reads (43%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as rs373477637, COSV99312803; called by muse, mutect2, varscan2
- C19orf44 | c.406dup p.S136Ffs*22 | Frame Shift Ins (INS) | VAF 35/74 reads (47%) | called by mutect2, pindel, varscan2
- DHX8 | c.3313_3320del p.K1105Lfs*7 | Frame Shift Del (DEL) | VAF 33/105 reads (31%) | called by mutect2, pindel, varscan2
- FTCD | c.1487dup p.N497Qfs*15 | Frame Shift Ins (INS) | VAF 29/49 reads (59%) | called by mutect2, pindel, varscan2
- RNF145 | c.483_487dup p.V163Afs*16 (on ENST00000424310 / NM_001199383.2; = p.V191Afs*16 on NM_144726.2) | Frame Shift Ins (INS) | VAF 155/207 reads (75%) | called by mutect2, varscan2
- SHE | c.297_335del p.K99_I112delinsN | In Frame Del (DEL) | VAF 29/68 reads (43%) | called by mutect2, pindel
- ADAMTS7 | c.429G>T p.L143= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV101183034; called by muse, mutect2, varscan2
- CNPY4 | c.249G>A p.E83= | Silent (SNP) | VAF 55/99 reads (56%) | catalogued as COSV99498770; called by muse, mutect2, varscan2
- COCH | c.1383T>G p.T461= (on ENST00000216361 / NM_001347720.1; = p.T396= on NM_004086.3) | Silent (SNP) | VAF 55/64 reads (86%) | catalogued as rs771767136, COSV99363435; called by muse, mutect2, varscan2
- LAMA1 | c.2874C>T p.S958= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs199612213; called by muse, mutect2, varscan2
- MACC1 | c.423A>C p.S141= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100255511; called by muse, mutect2, varscan2
- MAPRE3 | c.81C>T p.S27= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs1384264915, COSV99251573; called by muse, mutect2, varscan2
- MDGA1 | c.2055G>A p.Q685= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV99776450; called by muse, mutect2, varscan2
- MUC16 | c.36744T>A p.R12248= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs1019139089, COSV101198540, COSV101200319; called by muse, mutect2, varscan2
- PCDHA10 | c.180G>A p.Q60= | Silent (SNP) | VAF 101/118 reads (86%) | catalogued as COSV100248339; called by muse, mutect2, varscan2
- PKHD1 | c.10056T>C p.Y3352= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs1440812247, COSV100581602; called by muse, mutect2, varscan2
- RIMKLB | c.69A>G p.Q23= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100223782; called by muse, mutect2
- RP2 | c.300G>T p.V100= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99509090; called by muse, mutect2, varscan2
- SETD2 | c.4260G>A p.E1420= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV100338275; called by muse, mutect2, varscan2
- SF3A1 | c.2193C>G p.L731= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV99305255; called by muse, mutect2, varscan2
- TBX20 | c.75G>C p.S25= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV101282352; called by muse, mutect2, varscan2
- TXK | c.1053G>T p.L351= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV99972220; called by muse, mutect2
- WDR72 | c.1602C>T p.C534= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs765414382, COSV64741674, COSV64754512; called by muse, mutect2, varscan2
- ZNF10 | c.990C>T p.F330= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs964197905, COSV50211626, COSV99939999; called by muse, mutect2, varscan2
